Gene-level copy-number profile of tumor specimen TCGA-EK-A2RE-01A from TCGA case TCGA-EK-A2RE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 26.7 years (9,743 days).
Specimen TCGA-EK-A2RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.78c941e9-c082-49b4-8059-29938afdcb29.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2RE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b97c584-5742-40d6-9280-8b257952a39f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,097; copy number 2: 49,999; copy number 3: 4,693; copy number 5: 19; copy number 6: 4; copy number 9: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2RE-01A-11D-A18H-01): tumor purity 0.86, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,043,829–38,140,593, 5 genes, copy number 9: POU3F1, MIR3659HG, AL139158.1, MIR3659, LINC02786.
- chr9:29,214,322–29,318,952, 3 genes, copy number 6: AL162388.2, AL162388.1, AL353684.1.
- chr13:45,333,471–45,732,356, 19 genes, copy number 5: TPT1, SNORA31B, SNORA31, AL138963.3, TPT1-AS1, AL138963.1, RCN1P2, SLC25A30, SLC25A30-AS1, PPIAP25, COG3, ERICH6B, RNA5SP27, TIMM9P3, COX4I1P2, LINC01055, AKR1B1P4, CBY2, Metazoa_SRP.
- chr13:65,866,070–65,922,731, 1 gene, copy number 6 (within-gene range 3–6): LINC01052.

Autosomal genes at a single copy (total copy number 1): 5,097. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
